Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A059, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A059-01A (Primary Tumor).

[page 1 of 3]
Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries (
- 2: SP: Left external iliac lymph node
- 3: SP: Left hypogastric lymph node
- 4: SP: Left obturator lymph node
- 5: SP: Right external iliac lymph node
- 6: SP: Right obturator lymph node
- 7: SP: Left para-aortic lymph node
- 8: SP: Right para-aortic lymph nodes

1CD-0-3

adenocarcinoma, endometrioid, NOS

Site: endometrium C541

8380/3

for
6/24/11

DIAGNOSIS:

- 1) UTERUS CERVIX, FALLOPIAN TUBES AND OVARIES, RIGHT AND LEFT;
TOTAL HYSTERECTOMY BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, FIGO GRADE III (>
50% SOLID GROWTH), NUCLEAR GRADE 2 TO NUCLEAR GRADE 3 (SEE NOTE).
- THE TUMOR INVADDES TO <= HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 3 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION
IS 25 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO DEFINITE VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: COMPLEX HYPERPLASIA
WITH ATYPIA.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITIES: ADENOMYOSIS,
LEIOMYOMA(S).
- ALL ADNEXA ARE UNREMARKABLE.

NOTE: PARTS OF THE TUMOR ARE UNDIFFERENTIATED AND RESEMBLE SO-CALLED
LYMPHOEPITHELIOMA LIKE CARCINOMA. WE WILL PERFORM IMMUNOSTAINS FOR DNA
MISMATCH REPAIR PROTEINS BECAUSE EXTENSIVE LYMPHOCYTE INFILTRATION AND
UNDIFFERENTIATED MORPHOLOGY HAVE BEEN REPORTED IN PATIENTS WITH
MICROSATELLITE INSTABILITY-HIGH ENDOMETRIAL CANCERS THAT ARISE IN THE
SETTING OF PROMOTER HYPERMETHYLATION.

- 2) LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

** Continued on next page **

[page 2 of 3]
- 3) LYMPH NODES, LEFT HYPOGASTRIC, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 4) LYMPH NODES, LEFT OBTURATOR, EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 5) LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 6) LYMPH NODES, RIGHT OBTURATOR, EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 7) LYMPH NODE, LEFT PARA-AORTIC, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 8) LYMPH NODES, RIGHT PARA-AORTIC, EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 3]
Addendum Diagnosis

1. UTERUS, CERVIX, BILATERAL OVARIES AND FALLOPIAN TUBES; TOTAL
HYSTERECTOMY AND BILATERAL
SALPINGO-OOPHORECTOMY:
- IMMUNOHISTOCHEMICAL STAINS SHOW APPARENT LOSS OF MSH6 PROTEIN,
ALTHOUGH IT IS FOCALLY DIFFICULT TO DISTINGUISH STAINING IN STROMAL ELEMENTS
VERSUS RARE TUMOR CELLS. MLH1 AND MSH2 PROTEINS SHOW INTACT EXPRESSION.
- THE LOSS OF EXPRESSION OF MSH6, ALTHOUGH NOT DIAGNOSTIC, MAY SIGNIFY
THE PRESENCE OF
MICROSATELLITE INSTABILITY IN THIS PATIENT.
- PLEASE CORRELATE WITH GENETIC TESTING.

** End of Report **

Source: NCI Genomic Data Commons file 6cfaa2d1-0980-40da-b267-02c17e5dcd9d (TCGA-AP-A059.29A150D3-D5F0-4222-B082-6ABE35A2BB46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).